Somatic mutation profile of tumor specimen TCGA-3P-A9WA-01A (aliquot TCGA-3P-A9WA-01A-11D-A403-09) from TCGA case TCGA-3P-A9WA, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 55.3 years (20,211 days).
Specimen TCGA-3P-A9WA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 596647ae-e573-41c7-811a-02f719b5798a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3P-A9WA-10A (Blood Derived Normal), aliquot TCGA-3P-A9WA-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46a5d553-4e3a-4825-a94f-241184813893

The open-access MAF lists 137 somatic variants for this specimen: 101 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 29, Nonsense Mutation 9, Frame Shift Del 7, Splice Site 4, RNA 2, Intron 2, 3'UTR 1, In Frame Del 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs387907348, CM138025, COSV51993463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIAA1109 | c.3986A>G p.Y1329C | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs770791100, COSV52680542, COSV52695429; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3223C>T p.Q1075* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99792378; called by muse, mutect2, varscan2
- ABCF1 | c.107_109del p.K36del | In Frame Del (DEL) | VAF 38/94 reads (40%) | catalogued as rs776582273; called by pindel, varscan2
- AC126283.2 | c.114T>G p.Y38* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as COSV101144515; called by muse, mutect2, varscan2
- ACOT7 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100830220; called by muse, mutect2, varscan2
- ADGRL4 | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV66061726, COSV66062101; called by muse, mutect2, varscan2
- ADORA1 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100526476; called by muse, mutect2, varscan2
- AEBP1 | c.419A>T p.K140M | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99788860; called by muse, mutect2, varscan2
- AHNAK | c.17518G>T p.G5840W | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99947959; called by muse, mutect2, varscan2
- APEH | c.1427A>C p.N476T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99610848; called by muse, mutect2
- ASPHD1 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100441757; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4266G>T p.W1422C | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as CM131298, COSV100863801; called by muse, mutect2, varscan2
- BRD3 | c.714+1G>A p.X238_splice | Splice Site (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100325205; called by muse, mutect2, varscan2
- CAT | c.1518+2T>G p.X506_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99573284; called by muse, mutect2, varscan2
- CDH7 | c.1225A>T p.S409C | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100542581; called by muse, mutect2, varscan2
- CENPI | c.1331C>A p.P444H | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99515502; called by muse, mutect2, varscan2
- CES4A | c.1276T>C p.F426L | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1267777538, COSV100110124; called by muse, mutect2, varscan2
- COG1 | c.1593C>A p.D531E | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245345; called by muse, mutect2, varscan2
- COG1 | c.2329A>C p.M777L | Missense Mutation (SNP) | VAF 70/84 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100245346; called by muse, mutect2, varscan2
- CYLC1 | c.419C>A p.T140K | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100254846; called by muse, mutect2, varscan2
- DOCK11 | c.5609C>G p.T1870S | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52246786, COSV99354072; called by muse, mutect2, varscan2
- DPF2 | c.855G>C p.K285N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99361741; called by muse, mutect2, varscan2
- ENDOD1 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.87); catalogued as COSV99566610; called by muse, mutect2, varscan2
- ETNK1 | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99860786; called by muse, mutect2, varscan2
- EYS | c.596G>C p.S199T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.038); catalogued as rs767293146, COSV60996546; called by muse, mutect2, varscan2
- F9 | c.1083C>A p.H361Q | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99496636; called by muse, mutect2, varscan2
- FEZF1 | c.1295C>G p.T432R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100484502, COSV58659100; called by muse, mutect2, varscan2
- FZD7 | c.821C>A p.T274N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99637267; called by muse, varscan2
- GNPTAB | c.1673C>A p.P558Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100172069; called by muse, mutect2, varscan2
- GRM5 | c.196A>T p.I66F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100552443; called by muse, mutect2, varscan2
- GTPBP1 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as rs1249133946, COSV53286222; called by muse, mutect2, varscan2
- ILF2 | c.328A>G p.K110E | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as COSV100721955; called by muse, mutect2, varscan2
- IMPDH1 | c.1240G>A p.G414S (on ENST00000470772 / NM_001142573.2; = p.G500S on NM_000883.4) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV100118713; called by muse, mutect2, varscan2
- KCNJ4 | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100341294, COSV57857009; called by muse, mutect2, varscan2
- KDM2B | c.1848C>G p.C616W | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997453, COSV65638608; called by muse, mutect2, varscan2
- KIF16B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1228533508, COSV61704407; called by muse, mutect2, varscan2
- KIR3DL1 | c.398T>A p.L133Q | Missense Mutation (SNP) | VAF 71/79 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58487219; called by muse, mutect2, varscan2
- LAMC1 | c.4822A>G p.K1608E | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV99279763; called by muse, mutect2, varscan2
- LAMC3 | c.4636T>C p.F1546L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1401918921, COSV99908213; called by muse, mutect2, varscan2
- LAPTM4B | c.555C>A p.Y185* (on ENST00000445593; = p.Y94* on NM_018407.6) | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV101503494; called by muse, mutect2, varscan2
- LMBR1L | c.1201G>T p.V401F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV99918826; called by muse, mutect2, varscan2
- LRRK2 | c.3257A>T p.K1086I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV100110511; called by mutect2, varscan2
- LTB4R2 | c.106T>C p.Y36H (on ENST00000528054; = p.Y5H on NM_019839.5) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1229955764, COSV99350819; called by muse, mutect2, varscan2
- LUZP4 | c.319A>C p.N107H | Missense Mutation (SNP) | VAF 126/296 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100904857; called by muse, mutect2, varscan2
- MAP7D1 | c.2217C>A p.N739K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs1355956256, COSV100294572; called by muse, mutect2, varscan2
- MGA | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV99580326; called by muse, mutect2, varscan2
- MIDEAS | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV99678967; called by muse, mutect2, varscan2
- MRGBP | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100978287; called by muse, mutect2, varscan2
- MUC17 | c.5285T>A p.L1762H | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV100073784; called by muse, mutect2, varscan2
- NAGPA | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | PolyPhen benign (0.014); catalogued as COSV100392940; called by muse, mutect2, varscan2
- NAGPA | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | PolyPhen possibly damaging (0.534); catalogued as rs1199388261, COSV100392943; called by muse, mutect2, varscan2
- NUDT5 | c.517T>G p.L173V | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.266); catalogued as COSV100422138; called by muse, mutect2, varscan2
- NUP160 | c.2375T>A p.L792Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV101021520; called by muse, mutect2, varscan2
- OR10R2 | c.694_695del p.L232Vfs*20 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs747842707; called by mutect2, pindel, varscan2
- PAPOLG | c.2198C>G p.T733S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.206); catalogued as COSV99474816; called by muse, mutect2, varscan2
- PCDHGB4 | c.508T>G p.Y170D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99540207; called by muse, mutect2
- PDE3B | c.2914C>G p.P972A | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99962701; called by muse, mutect2, varscan2
- PFN2 | c.223A>G p.R75G | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99526081; called by muse, mutect2, varscan2
- PGM1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV100936605; called by muse, mutect2, varscan2
- PHKA1 | c.1173C>A p.D391E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as COSV100263427; called by muse, mutect2, varscan2
- PNMA1 | c.1000A>G p.K334E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs141898620; called by muse, mutect2, varscan2
- PRSS1 | c.554G>C p.C185S | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100298063; called by muse, mutect2, varscan2
- RAB21 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); catalogued as COSV99714853; called by muse, mutect2, varscan2
- SARDH | c.2326+1G>T p.X776_splice | Splice Site (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100898422; called by muse, mutect2, varscan2
- SLC12A6 | c.1544C>A p.S515Y (on ENST00000354181 / NM_001365088.1; = p.S464Y on NM_005135.2) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99272326; called by muse, mutect2, varscan2
- SLC28A2 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754741; called by muse, mutect2, varscan2
- SLCO1B3 | c.1944G>C p.K648N | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99681613; called by muse, mutect2, varscan2
- SMC4 | c.377T>A p.M126K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100424840; called by muse, mutect2, varscan2
- SORBS1 | c.611T>C p.F204S (on ENST00000361941 / NM_001034954.2; = p.F172S on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as COSV99528297; called by muse, mutect2, varscan2
- SPATA12 | c.76T>C p.S26P | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100534698; called by muse, mutect2, varscan2
- SPG11 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.112); catalogued as COSV99968894; called by muse, mutect2
- SPIB | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99570015; called by muse, mutect2, varscan2
- SPSB2 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.371); catalogued as COSV99222930, COSV99223009; called by muse, mutect2, varscan2
- SRPK3 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99473221; called by muse, mutect2, varscan2
- STRIP1 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100873969; called by muse, mutect2, varscan2
- STYXL2 | c.1311C>A p.S437R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.271); catalogued as COSV99609401; called by muse, mutect2, varscan2
- SULT1A1 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100131906; called by muse, mutect2, varscan2
- SWAP70 | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100013844; called by muse, mutect2, varscan2
- SYDE2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV52319137; called by muse, mutect2, varscan2
- SYT6 | c.1364G>A p.R455Q (on ENST00000610222 / NM_001366225.1; = p.R370Q on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.958); catalogued as rs752518998, COSV101059651; called by muse, mutect2, varscan2
- TAFA4 | c.404C>G p.T135S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99807218; called by muse, mutect2, varscan2
- TFAP4 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99200068; called by muse, mutect2, varscan2
- TRPM1 | c.3922G>T p.E1308* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV56642706, COSV99856092; called by muse, mutect2, varscan2
- TTF1 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV57503761; called by muse, mutect2, varscan2
- WWC2 | c.3118C>T p.R1040C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1482664879, COSV101330967; called by muse, mutect2, varscan2
- ZNF280C | c.9C>G p.D3E | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV100921246, COSV63970125; called by muse, mutect2, varscan2
- ZNF862 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV56222579, COSV99783558; called by muse, mutect2, varscan2
- A2ML1 | c.3095A>G p.N1032S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- CBWD5 | c.791C>G p.P264R (on ENST00000382405 / NM_001330668.1; = p.P216R on NM_001024916.3) | Missense Mutation (SNP) | VAF 196/682 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDHR4 | c.457_458del p.T153Sfs*32 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2
- CYP7B1 | c.1280_1281del p.T427Ifs*44 | Frame Shift Del (DEL) | VAF 29/142 reads (20%) | called by mutect2, pindel, varscan2
- DENND6A | c.274_275del p.E92Kfs*25 | Frame Shift Del (DEL) | VAF 40/201 reads (20%) | called by pindel, varscan2
- IGHG3 | c.728del p.W243Cfs*2 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel*, varscan2
- ISOC1 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- LSG1 | c.1487_1488del p.E496Gfs*2 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by pindel, varscan2
- PPARD | c.685A>T p.K229* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- PPARD | c.686A>G p.K229R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RBM5 | c.186_189del p.X62_splice | Splice Site (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- STIL | c.2666_2681del p.S889Kfs*3 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- ADI1 | c.504C>T p.R168= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs144167517; called by muse, mutect2, varscan2
- AMPD1 | c.1608C>G p.L536= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV100815086; called by muse, mutect2, varscan2
- ARFGEF2 | c.1584C>T p.N528= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV100904317; called by muse, mutect2, varscan2
- ARHGAP21 | c.3690C>G p.L1230= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as COSV100256345, COSV100256694; called by muse, mutect2, varscan2
- C11orf24 | c.1197A>G p.K399= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100422604; called by muse, mutect2, varscan2
- CDH7 | c.1224T>C p.N408= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs762181328, COSV100542580; called by muse, mutect2, varscan2
- CDKN2B | c.120C>G p.P40= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99439579; called by muse, mutect2, varscan2
- CITED2 | c.357C>T p.L119= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs371790523, COSV100863117; called by muse, mutect2, varscan2
- CLIP2 | c.375C>T p.G125= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs782770325, COSV99791714; called by muse, mutect2, varscan2
- CNOT1 | c.5811T>C p.D1937= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV99800460; called by muse, mutect2, varscan2
- COL8A1 | c.1107G>A p.G369= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1472390287, COSV99657929; called by muse, mutect2, varscan2
- DENND1C | c.1002A>G p.K334= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as COSV101200214; called by muse, mutect2, varscan2
- DTX3L | c.1614T>C p.A538= | Silent (SNP) | VAF 27/32 reads (84%) | catalogued as COSV56144463; called by muse, mutect2, varscan2
- GATA3 | c.1149G>A p.E383= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100651059; called by muse, mutect2, varscan2
- GPR135 | c.1266G>A p.L422= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101229327; called by muse, mutect2
- HYAL2 | c.936T>C p.S312= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100753912; called by muse, mutect2, varscan2
- LMBR1L | c.1200G>T p.L400= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99918828; called by muse, mutect2, varscan2
- MYOM1 | c.1542G>A p.L514= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs1567938514, COSV99867067; called by muse, mutect2
- NOX1 | c.408C>A p.S136= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV54195591, COSV99471590; called by muse, mutect2, varscan2
- PRKD1 | c.1794T>C p.Y598= | Silent (SNP) | VAF 58/266 reads (22%) | catalogued as rs764588984, COSV100120604; called by muse, mutect2, varscan2
- SLC25A39 | c.375C>T p.S125= (on ENST00000377095 / NM_001143780.3; = p.S117= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs746520320, COSV56589562; called by muse, mutect2, varscan2
- SLU7 | c.1161T>A p.A387= | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as COSV99775686; called by muse, mutect2, varscan2
- SPTB | c.5688G>C p.R1896= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV101072196, COSV67632335; called by muse, mutect2, varscan2
- SSX3 | c.147G>A p.V49= | Silent (SNP) | VAF 159/389 reads (41%) | catalogued as COSV100035298; called by muse, mutect2, varscan2
- TLR8 | c.2895G>A p.Q965= (on ENST00000218032 / NM_138636.5; = p.Q983= on NM_016610.4) | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV99487086; called by muse, mutect2, varscan2
- TMEM39A | c.162C>A p.I54= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100052446; called by muse, mutect2
- TOB2 | c.327G>T p.V109= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100548451, COSV59500273; called by muse, mutect2, varscan2
- ZCCHC7 | c.231T>G p.L77= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100383207; called by muse, mutect2, varscan2
- ZNF282 | c.246C>T p.P82= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs190208939; called by muse, mutect2, varscan2
- C1orf220 | n.375T>C | RNA (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- HYPK | c.-15C>G | 5'UTR (SNP) | VAF 18/32 reads (56%) | catalogued as COSV99979927; called by muse, mutect2, varscan2
- LARS2 | c.*410A>T | 3'UTR (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99647905; called by muse, mutect2, varscan2
- PPP1R1A | chr12:54577478 del AT | 3'Flank (DEL) | VAF 14/37 reads (38%) | catalogued as rs747434837; called by mutect2, pindel, varscan2
- RBFOX2 | c.1150-3868A>G | Intron (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99455504; called by muse, mutect2, varscan2
- RPGR | c.2520+116G>T | Intron (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100140106; called by muse, mutect2, varscan2
- SLC35E2A | n.743G>A | RNA (SNP) | VAF 12/190 reads (6%) | catalogued as rs754011804, COSV99870809; called by muse, mutect2
